MMRF case MMRF_2211 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/129a4a90-3414-4879-985a-c49bde58d837

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 45.5 years (16,609 days); ISS stage: III; Days to last known disease status: 907 days (2.5 years); Days to last follow up: 907 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 36 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 120 days; Days to treatment end: 120 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 249 days; Days to treatment end: 384 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 396 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3: M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1031 mg/dL; Immunoglobulin G 6.49 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 7.88 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3.15 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 210 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 5.67 mmol/L; C-Reactive Protein 2.6 mg/dL.
- Day 60: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 4.77 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 1.85 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.46 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 5.17 mmol/L.
- Day 148 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.5 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 2.28 g/L; Immunoglobulin M 0.52 g/L; Beta 2 Microglobulin 3.45 µg/mL; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.39 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 6.4 g/dL; Glucose 7.37 mmol/L.
- Day 249 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.8 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 3.3 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 2.48 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.08 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 127 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7.7 g/dL; Glucose 6.93 mmol/L.
- Day 368 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Immunoglobulin G 15.6 g/L; Immunoglobulin A 2.95 g/L; Immunoglobulin M 0.64 g/L; Beta 2 Microglobulin 1.82 µg/mL; Hemoglobin 9.05 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.36 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 8.1 g/dL; Glucose 5.12 mmol/L.
- Day 459 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.67 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 2.41 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 1.89 µg/mL; Lactate Dehydrogenase 2 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 0.96 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 45 g/L; Total Protein 7.9 g/dL; Glucose 5.23 mmol/L.
- Day 529 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.95 mg/dL; Immunoglobulin G 15.6 g/L; Immunoglobulin A 2.63 g/L; Immunoglobulin M 0.64 g/L; Beta 2 Microglobulin 1.71 µg/mL; Lactate Dehydrogenase 2 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.01 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 5.06 mmol/L.
- Day 641 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.7 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 2.29 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 1.59 µg/mL; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 0.67 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 125 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.94 mmol/L.
- Day 690 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.71 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 2.49 g/L; Immunoglobulin M 0.56 g/L; Beta 2 Microglobulin 1.17 µg/mL; Lactate Dehydrogenase 1.82 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.13 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 5.01 mmol/L.
- Day 753 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.03 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 2.64 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 0.37 µg/mL; Lactate Dehydrogenase 1.8 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 0.77 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 4.46 mmol/L.
- Day 907 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.06 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 2.2 g/L; Immunoglobulin M 0.56 g/L; Beta 2 Microglobulin 1.31 µg/mL; Lactate Dehydrogenase 1.75 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.54 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7.6 g/dL; Glucose 5.01 mmol/L.

Other clinical attributes
- Day -3: Weight: 110 kg; Height: 193 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2211_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_2211_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
